Somatic mutation profile of tumor specimen 0DUXOZ from CCDI case PBCLVB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,581 days).
Specimen 0DUXOZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aec5d705-a850-46f4-a860-37cd9fc00d4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64f9babf-77d5-4691-91c0-0445d3be66b0

The open-access MAF lists 12 somatic variants for this specimen: 3 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Intron 3, Missense Mutation 1, Splice Region 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, varscan2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 20/224 reads (9%) | catalogued as COSV59989381; called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- CAPRIN2 | c.1782+78T>A | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, varscan2
- FBXW7 | c.*68G>A | 3'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs1407731604; called by muse, varscan2
- IKBKB | c.1689-92G>C | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- MAP3K12 | c.*58A>G | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs1334265512; called by muse, varscan2
- MAP3K12 | c.*57C>T | 3'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as rs1018838665, COSV99913570; called by muse, varscan2
- MCM7 | c.276+86G>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 8/63 reads (13%) | called by muse, varscan2
- TMEM178B | c.*33A>T | 3'UTR (SNP) | VAF 8/44 reads (18%) | catalogued as rs1434668436; called by muse, varscan2
- TMEM178B | c.*34A>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
